Somatic mutation profile of tumor specimen 0DV4J8 from CCDI case PBCMIR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (168 days).
Specimen 0DV4J8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aa09d34-21f2-4c63-bbf6-6c3cee6076c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/860bfc3f-3896-46af-8c08-2cadd353c5d4

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 30/424 reads (7%) | catalogued as rs1085307984, CM107259, COSV56134117; ClinVar: pathogenic; called by muse, mutect2
- OR4Q2 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
